Somatic mutation profile of tumor specimen TCGA-56-8083-01A (aliquot TCGA-56-8083-01A-11D-2244-08) from TCGA case TCGA-56-8083, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 56.7 years (20,696 days).
Specimen TCGA-56-8083-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35609ac1-d4a3-4a40-a053-de61d599387b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8083-10A (Blood Derived Normal), aliquot TCGA-56-8083-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9caf26eb-38a6-49be-bc72-3fa6fe56e8d9

The open-access MAF lists 186 somatic variants for this specimen: 138 protein-altering or splice-affecting, 45 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 45, Nonsense Mutation 12, Frame Shift Del 9, Splice Site 4, 3'UTR 2, Frame Shift Ins 2, Intron 1, In Frame Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.902del p.P301Qfs*44 | Frame Shift Del (DEL) | VAF 54/93 reads (58%) | catalogued as rs876660726, COSV53267099, COSV53486315; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACACB | c.988G>C p.A330P | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100622466; called by muse, mutect2, varscan2
- ADAD1 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.56); catalogued as COSV99635224; called by muse, mutect2, varscan2
- ANKRD30A | c.620C>T p.T207I (on ENST00000611781; = p.T151I on NM_052997.2) | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100653074; called by muse, mutect2, varscan2
- ANKRD34B | c.578C>A p.T193N | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100103408; called by muse, mutect2, varscan2
- ANO3 | c.1732C>A p.Q578K | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99881271; called by muse, mutect2, varscan2
- AQP11 | c.229T>C p.W77R | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); catalogued as COSV57992839; called by muse, mutect2, varscan2
- ARHGAP27 | c.2003G>A p.R668Q (on ENST00000428638 / NM_001282290.1; = p.R327Q on NM_199282.3) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100976467; called by muse, varscan2
- ATMIN | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746244993, COSV55146360; called by muse, mutect2, varscan2
- BRCA2 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101204001; called by muse, mutect2, varscan2
- BTN3A1 | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99175657; called by muse, mutect2, varscan2
- BUD23 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 77/125 reads (62%) | catalogued as rs1195540508, COSV56095882; called by muse, mutect2, varscan2
- C6 | c.2609G>A p.W870* | Nonsense Mutation (SNP) | VAF 562/798 reads (70%) | catalogued as COSV99666679; called by muse, varscan2
- CAMTA1 | c.3118G>A p.V1040M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750811156, COSV100347087; called by muse, mutect2, varscan2
- CCAR1 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56271148; called by muse, mutect2, varscan2
- CCDC141 | c.1911C>A p.N637K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV99836360; called by muse, mutect2, varscan2
- CD101 | c.1435A>T p.S479C | Missense Mutation (SNP) | VAF 96/206 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV99869244; called by muse, mutect2, varscan2
- CD300LB | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 94/239 reads (39%) | catalogued as COSV100075342; called by muse, mutect2, varscan2
- CDH18 | c.1999G>T p.D667Y | Missense Mutation (SNP) | VAF 78/384 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99932754; called by muse, mutect2, varscan2
- CDH8 | c.1534C>A p.Q512K | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); catalogued as COSV100180029; called by muse, mutect2, varscan2
- CHRDL1 | c.365T>C p.F122S (on ENST00000372045; = p.F128S on NM_145234.4) | Missense Mutation (SNP) | VAF 158/172 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99487796; called by muse, mutect2, varscan2
- CILP2 | c.1656G>C p.K552N | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1568369966, COSV52279720, COSV99364421; called by muse, mutect2, varscan2
- CMC2 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs745359055, COSV99548140; called by muse, mutect2, varscan2
- COL11A1 | c.4465-2A>T p.X1489_splice | Splice Site (SNP) | VAF 53/159 reads (33%) | catalogued as COSV100615456; called by muse, mutect2, varscan2
- COL11A1 | c.3568T>C p.F1190L | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as rs1377819809, COSV100615457; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL20A1 | c.564G>A p.W188* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as rs571535477, COSV100490061; called by muse, mutect2, varscan2
- COLEC11 | c.395T>A p.L132Q | Missense Mutation (SNP) | VAF 71/80 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99362937; called by muse, mutect2, varscan2
- COLEC12 | c.1744C>A p.P582T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.542); catalogued as COSV101231988; called by muse, mutect2
- CSF1R | c.1958G>T p.C653F | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1210217, COSV99641127; called by muse, varscan2
- CSMD2 | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99587110; called by muse, mutect2, varscan2
- DIAPH2 | c.870-2A>T p.X290_splice | Splice Site (SNP) | VAF 19/20 reads (95%) | catalogued as COSV100231461; called by muse, mutect2, varscan2
- DLC1 | c.1847C>A p.P616H (on ENST00000276297 / NM_001348081.2; = p.P179H on NM_006094.5) | Missense Mutation (SNP) | VAF 68/80 reads (85%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV99361751; called by muse, mutect2, varscan2
- DNAH17 | c.2741C>A p.P914Q | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101101682, COSV67761060; called by muse, mutect2, varscan2
- DPF3 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs781541440, COSV100818442; called by muse, varscan2
- EHBP1L1 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100499731; called by muse, mutect2, varscan2
- EXOC2 | c.1255G>C p.G419R | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV100033153; called by muse, mutect2, varscan2
- FADS2 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as COSV99608481; called by muse, mutect2, varscan2
- FAM83C | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.879); catalogued as COSV100981529; called by muse, mutect2, varscan2
- FAM9B | c.393+2T>A p.X131_splice | Splice Site (SNP) | VAF 10/11 reads (91%) | catalogued as COSV100510903; called by muse, mutect2, varscan2
- FANCM | c.4597G>T p.E1533* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99950643; called by muse, mutect2, varscan2
- FCRL3 | c.1859A>T p.Q620L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100942945; called by muse, mutect2, varscan2
- FECH | c.1190A>T p.K397M | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.402); catalogued as COSV100023438; called by muse, mutect2, varscan2
- FYN | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 78/185 reads (42%) | catalogued as COSV99991286, COSV99991657; called by muse, mutect2, varscan2
- GFRAL | c.626C>A p.T209K | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV100474756, COSV100475369; called by muse, mutect2, varscan2
- GIMAP7 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as rs145339506, COSV57959733; called by muse, mutect2, varscan2
- GRAMD1A | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); catalogued as COSV100526025; called by muse, mutect2, varscan2
- GTF3C4 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100935929; called by muse, mutect2, varscan2
- GTSF1L | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100883905; called by muse, mutect2, varscan2
- HECW1 | c.2668C>G p.R890G | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101222992, COSV67821831; called by muse, varscan2
- HIP1R | c.2438C>A p.S813* | Nonsense Mutation (SNP) | VAF 40/96 reads (42%) | catalogued as COSV99458404; called by muse, mutect2, varscan2
- HTATSF1 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 46/52 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1340934996, COSV54478671; called by muse, mutect2, varscan2
- INPPL1 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 45/432 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs749091098, COSV99995963; called by muse, mutect2, varscan2
- IRF2BP1 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV100138821; called by muse, mutect2, varscan2
- KALRN | c.8393G>T p.R2798M (on ENST00000360013 / NM_001024660.4; = p.R1101M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99361321; called by muse, mutect2, varscan2
- KBTBD12 | c.602G>T p.W201L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100675378, COSV59678106; called by muse, mutect2, varscan2
- KCNH7 | c.1486T>C p.W496R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100034529; called by muse, mutect2, varscan2
- KHDC3L | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs757863032, COSV100951072; called by muse, mutect2, varscan2
- KIAA1755 | c.3496C>A p.Q1166K | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99641632; called by muse, mutect2, varscan2
- KIF17 | c.2554C>A p.R852S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99928681; called by muse, mutect2, varscan2
- KLHL1 | c.1684G>T p.D562Y | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100917082; called by muse, mutect2, varscan2
- KLHL41 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52930080; called by muse, mutect2, varscan2
- MCHR2 | c.937T>A p.F313I | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV99911651; called by muse, mutect2, varscan2
- MCPH1 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100765430; called by muse, mutect2, varscan2
- MEP1B | c.1033T>G p.L345V | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV99328729; called by muse, mutect2, varscan2
- MMRN1 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as rs369585513; called by muse, mutect2, varscan2
- MUC5B | c.5024C>A p.T1675K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.37); catalogued as rs758528992, COSV101500097, COSV71596525; called by muse, mutect2, varscan2
- MYO7B | c.3649T>G p.S1217A | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV101267949; called by muse, mutect2, varscan2
- MYPN | c.532T>A p.C178S | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as COSV62733676; called by muse, mutect2, varscan2
- NAV3 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.015); catalogued as rs189238808, COSV99887918; called by muse, mutect2, varscan2
- NLRP7 | c.1182C>A p.F394L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV100051836, COSV60173199; called by muse, mutect2, varscan2
- NPAS3 | c.712C>A p.Q238K (on ENST00000356141 / NM_001164749.2; = p.Q206K on NM_022123.3) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.17); catalogued as COSV100386586; called by muse, mutect2, varscan2
- NPC1L1 | c.545C>A p.T182K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV56922156, COSV99203115; called by muse, mutect2, varscan2
- NUP153 | c.2617G>T p.A873S | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100019951; called by muse, mutect2, varscan2
- NUP98 | c.2451-2A>G p.X817_splice | Splice Site (SNP) | VAF 27/59 reads (46%) | catalogued as COSV100261711; called by muse, mutect2, varscan2
- OR2B2 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs930939827, COSV57579181; called by muse, mutect2, varscan2
- OR51T1 | c.816G>T p.R272S | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs772529902, COSV59025161, COSV59027687; called by muse, mutect2, varscan2
- OR6C4 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs973606564, COSV101263132; called by muse, mutect2, varscan2
- PCDH15 | c.5017G>T p.V1673F | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0.04); catalogued as COSV100903421; called by muse, varscan2
- PDE4DIP | c.2790del p.R930Sfs*80 | Frame Shift Del (DEL) | VAF 72/206 reads (35%) | catalogued as COSV57723504; called by mutect2, pindel, varscan2
- PEAK1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200745735, COSV100432611; called by muse, mutect2, varscan2
- PHF21A | c.1130A>C p.H377P (on ENST00000418153 / NM_001101802.3; = p.H378P on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs1168943586, COSV99138116; called by muse, mutect2, varscan2
- PKHD1 | c.5789G>T p.R1930M | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV100581682; called by muse, mutect2, varscan2
- PKP3 | c.909C>G p.Y303* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100520745, COSV58988886; called by muse, mutect2, varscan2
- POM121L12 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs767476421, COSV101374867; called by muse, mutect2, varscan2
- PPARG | c.1363G>T p.E455* (on ENST00000287820 / NM_015869.5; = p.E425* on NM_005037.7) | Nonsense Mutation (SNP) | VAF 23/27 reads (85%) | catalogued as COSV55143820, COSV99826341; called by muse, mutect2, varscan2
- PPFIBP2 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV100206170; called by muse, mutect2, varscan2
- PRORP | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV99155004; called by muse, mutect2, varscan2
- PTPRB | c.4979G>A p.R1660H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as rs778052516, COSV54244676, COSV99716272; called by muse, mutect2, varscan2
- PTPRR | c.1496A>T p.E499V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99316604; called by muse, mutect2, varscan2
- PWWP3B | c.1004G>T p.S335I | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV100531022; called by muse, mutect2, varscan2
- RASSF2 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV101040666, COSV65083493; called by muse, mutect2, varscan2
- RBM45 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV99617547; called by muse, mutect2, varscan2
- RGS1 | c.427T>G p.S143A | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV100817404; called by muse, mutect2, varscan2
- RHCG | c.170A>T p.Y57F | Missense Mutation (SNP) | VAF 103/222 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV99174077; called by muse, mutect2, varscan2
- ROBO2 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100164864, COSV59940480; called by muse, mutect2, varscan2
- ROS1 | c.4746C>A p.H1582Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV100876623; called by muse, mutect2, varscan2
- RPL23 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99834659; called by muse, mutect2, varscan2
- SCN9A | c.319T>C p.Y107H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV100311798; called by muse, mutect2, varscan2
- SELE | c.409C>A p.L137I | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100324467; called by muse, mutect2, varscan2
- SESTD1 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV100090274; called by muse, mutect2, varscan2
- SLX4 | c.2094C>G p.D698E | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99567731; called by muse, mutect2, varscan2
- SPEG | c.4981C>A p.H1661N | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100403580; called by muse, mutect2, varscan2
- SPOCK3 | c.173G>T p.W58L | Missense Mutation (SNP) | VAF 78/88 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100692179; called by muse, mutect2, varscan2
- SPTA1 | c.7006C>A p.L2336M | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100934526; called by muse, mutect2, varscan2
- STMN4 | c.164T>A p.L55Q (on ENST00000265770 / NM_001283054.2; = p.L82Q on NM_030795.4) | Missense Mutation (SNP) | VAF 58/74 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56109215, COSV99740690; called by muse, mutect2, varscan2
- TANC2 | c.3532G>T p.D1178Y | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101267281; called by muse, mutect2, varscan2
- THBS2 | c.2357C>A p.A786D | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as COSV64681737, COSV64682616; called by muse, mutect2
- TIMMDC1 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 69/164 reads (42%) | catalogued as COSV99956089; called by muse, mutect2, varscan2
- TMPRSS11F | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.434); catalogued as COSV100678264, COSV62469031; called by muse, mutect2
- TNR | c.480C>G p.C160W | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99688194; called by muse, mutect2, varscan2
- TRIM3 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1227828415, COSV100624277; called by muse, mutect2, varscan2
- TRIM37 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99232454; called by muse, mutect2, varscan2
- TSC22D1 | c.2869G>T p.V957L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV101488072; called by muse, mutect2, varscan2
- TTN | c.80129A>G p.D26710G (on ENST00000591111; = p.D19286G on NM_003319.4) | Missense Mutation (SNP) | VAF 74/171 reads (43%) | PolyPhen possibly damaging (0.603); catalogued as COSV100599448; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3116G>C p.G1039A | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99691245; called by muse, mutect2, varscan2
- UNC13C | c.392T>A p.L131* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99513071; called by muse, mutect2, varscan2
- VANGL1 | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as COSV100048931, COSV59620415; called by muse, mutect2, varscan2
- VN1R4 | c.132G>T p.L44F | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV100237346; called by muse, mutect2
- YIPF7 | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs1312357612, COSV100274389, COSV60657099; called by muse, mutect2, varscan2
- ZBBX | c.2288G>A p.R763K | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100283331, COSV100283696, COSV56799832; called by muse, mutect2, varscan2
- ZBTB7B | c.711G>T p.E237D (on ENST00000292176; = p.E271D on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99420920; called by muse, mutect2, varscan2
- ZNF423 | c.2311G>C p.A771P (on ENST00000563137 / NM_001379286.1; = p.A763P on NM_015069.4) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.445); catalogued as COSV99280440; called by muse, mutect2, varscan2
- ZNF492 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as rs1266458394, COSV101513957; called by muse, mutect2, varscan2
- ZNF836 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100440686; called by muse, mutect2, varscan2
- ZZEF1 | c.4574G>C p.R1525P | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); catalogued as COSV101067600, COSV67559088; called by muse, mutect2, varscan2
- ABCG2 | c.1744del p.Q582Sfs*34 | Frame Shift Del (DEL) | VAF 24/85 reads (28%) | called by pindel, varscan2
- ACOX1 | c.1626del p.K542Nfs*14 | Frame Shift Del (DEL) | VAF 47/131 reads (36%) | called by mutect2, pindel, varscan2
- CFAP46 | c.6012del p.T2005Qfs*24 | Frame Shift Del (DEL) | VAF 53/167 reads (32%) | called by mutect2, pindel, varscan2
- CTBP2 | c.633dup p.Y212Lfs*38 | Frame Shift Ins (INS) | VAF 41/118 reads (35%) | called by mutect2, pindel, varscan2
- GAGE10 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- IGLV3-25 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- ITPR3 | c.7516_7521dup p.I2506_I2507dup | In Frame Ins (INS) | VAF 27/115 reads (23%) | called by mutect2, pindel, varscan2
- NLRP8 | c.1158del p.N386Kfs*21 | Frame Shift Del (DEL) | VAF 34/143 reads (24%) | called by mutect2, pindel, varscan2
- P2RY8 | c.756del p.N253Tfs*10 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- SIX4 | c.1112_1113del p.Q371Rfs*8 | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | called by mutect2, pindel, varscan2
- SNURF | c.104dup p.N35Kfs*24 | Frame Shift Ins (INS) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.727G>C p.V243L | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF488 | c.865del p.D289Tfs*48 | Frame Shift Del (DEL) | VAF 38/92 reads (41%) | called by mutect2, pindel, varscan2
- ADAM21 | c.1857C>T p.C619= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as COSV99960655; called by muse, mutect2, varscan2
- ADAM23 | c.1173G>C p.R391= | Silent (SNP) | VAF 60/105 reads (57%) | catalogued as COSV100006981; called by muse, mutect2, varscan2
- ANAPC2 | c.657G>A p.P219= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as rs1374216157, COSV58809368; called by muse, mutect2, varscan2
- ANGPT2 | c.777G>C p.L259= | Silent (SNP) | VAF 43/59 reads (73%) | catalogued as COSV100290711; called by muse, mutect2, varscan2
- APC | c.8338A>C p.R2780= | Silent (SNP) | VAF 41/50 reads (82%) | catalogued as COSV99965981; called by muse, mutect2, varscan2
- CAPN11 | c.1821C>A p.T607= | Silent (SNP) | VAF 116/299 reads (39%) | catalogued as COSV101291856; called by muse, mutect2, varscan2
- CCKBR | c.594G>T p.V198= | Silent (SNP) | VAF 62/150 reads (41%) | catalogued as COSV100582791; called by muse, mutect2, varscan2
- CIRBP | c.357G>T p.G119= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV100309722; called by muse, mutect2, varscan2
- CNTD1 | c.273C>T p.I91= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100162058; called by muse, mutect2, varscan2
- COL11A1 | c.1137C>A p.G379= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100615459, COSV62173679; called by muse, mutect2, varscan2
- CSTF1 | c.1176G>T p.L392= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV99410110; called by muse, mutect2, varscan2
- CYP2D6 | c.681C>A p.V227= | Silent (SNP) | VAF 66/103 reads (64%) | catalogued as COSV100637257; called by muse, mutect2, varscan2
- FGD2 | c.975G>T p.P325= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs755559160, COSV99235947; called by muse, mutect2, varscan2
- GAN | c.1494G>A p.E498= | Silent (SNP) | VAF 60/163 reads (37%) | catalogued as rs755423556, COSV73721629; called by muse, mutect2, varscan2
- HSPA1L | c.714G>A p.R238= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as COSV100989344; called by muse, mutect2, varscan2
- HYDIN | c.9018T>A p.P3006= | Silent (SNP) | VAF 56/242 reads (23%) | catalogued as COSV99992197; called by muse, varscan2
- HYDIN | c.6825C>A p.A2275= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as COSV59252892, COSV99992202; called by muse, mutect2, varscan2
- MDGA2 | c.1812C>A p.I604= (on ENST00000399232 / NM_001113498.2; = p.I306= on NM_182830.4) | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as COSV100636530; called by muse, mutect2, varscan2
- MUC3A | c.7155C>T p.P2385= | Silent (SNP) | VAF 164/218 reads (75%) | catalogued as rs536690800, COSV60210106; called by muse, mutect2, varscan2
- MYO1D | c.2625A>G p.R875= | Silent (SNP) | VAF 74/162 reads (46%) | catalogued as COSV100553684; called by muse, mutect2, varscan2
- NME7 | c.282G>T p.T94= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100890925; called by muse, mutect2, varscan2
- NSG1 | c.234C>A p.T78= | Silent (SNP) | VAF 25/27 reads (93%) | catalogued as COSV101207915, COSV67574639; called by muse, mutect2, varscan2
- NTRK2 | c.1707G>T p.V569= (on ENST00000323115 / NM_001369534.1; = p.V585= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99453280; called by muse, mutect2, varscan2
- NUP107 | c.1569C>T p.D523= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99971575; called by muse, mutect2, varscan2
- OR2M2 | c.525C>T p.A175= | Silent (SNP) | VAF 129/521 reads (25%) | catalogued as COSV100677190, COSV62898846; called by muse, mutect2, varscan2
- OR8D4 | c.228C>A p.V76= | Silent (SNP) | VAF 220/243 reads (91%) | catalogued as COSV100361724; called by muse, mutect2, varscan2
- PABPC5 | c.1104C>T p.S368= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV100442172; called by muse, mutect2, varscan2
- PC | c.729G>T p.R243= | Silent (SNP) | VAF 80/177 reads (45%) | catalogued as rs755610533, COSV100852086; called by muse, mutect2, varscan2
- PDHA2 | c.363G>A p.V121= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV99756603; called by muse, mutect2, varscan2
- PRDM9 | c.2478C>T p.H826= | Silent (SNP) | VAF 130/424 reads (31%) | catalogued as COSV57007476, COSV99689938; called by muse, mutect2, varscan2
- PRORP | c.447T>C p.A149= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as COSV99155001; called by muse, mutect2, varscan2
- PTPRB | c.1230C>T p.I410= | Silent (SNP) | VAF 58/143 reads (41%) | catalogued as COSV54239480, COSV99716277; called by muse, mutect2, varscan2
- RELCH | c.477G>C p.G159= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99901569; called by muse, mutect2
- SEMA5B | c.2814C>A p.T938= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99531069; called by muse, mutect2, varscan2
- SEMA6B | c.1083C>A p.I361= | Silent (SNP) | VAF 37/48 reads (77%) | catalogued as COSV100014694; called by muse, mutect2, varscan2
- SERPINI1 | c.174A>C p.G58= | Silent (SNP) | VAF 39/231 reads (17%) | catalogued as COSV99854894; called by muse, mutect2, varscan2
- SHKBP1 | c.726G>A p.A242= | Silent (SNP) | VAF 81/139 reads (58%) | catalogued as rs757707437, COSV99398966; called by muse, mutect2, varscan2
- SLC25A3 | c.654G>A p.K218= (on ENST00000228318 / NM_005888.3; = p.K217= on NM_002635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV99499023; called by muse, mutect2, varscan2
- SLC7A13 | c.102C>A p.S34= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as COSV52538164, COSV99878600; called by muse, mutect2, varscan2
- TCF20 | c.3849C>T p.R1283= | Silent (SNP) | VAF 47/178 reads (26%) | catalogued as COSV100166360; called by muse, mutect2, varscan2
- TPCN2 | c.420C>G p.L140= | Silent (SNP) | VAF 96/1707 reads (6%) | catalogued as COSV99593287; called by muse, mutect2
- TRIM6-TRIM34 | c.2043A>T p.P681= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100708934; called by muse, mutect2, varscan2
- TTN | c.34569G>A p.A11523= (on ENST00000591111; = p.A10596= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/146 reads (42%) | catalogued as rs375519815; ClinVar: likely benign / uncertain significance / benign; called by muse, mutect2, varscan2
- WAPL | c.744A>T p.S248= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV100076564, COSV100077222; called by muse, mutect2, varscan2
- ZMYM1 | c.1650T>C p.N550= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as COSV100720909; called by muse, mutect2, varscan2
- CLRN1 | c.*2del | 3'UTR (DEL) | VAF 14/95 reads (15%) | called by mutect2, pindel, varscan2
- NR1I2 | c.-23+534C>A | Intron (SNP) | VAF 26/61 reads (43%) | catalogued as COSV100561479; called by muse, mutect2, varscan2
- VNN3 | c.*570T>A | 3'UTR (SNP) | VAF 23/39 reads (59%) | catalogued as COSV99258094; called by muse, mutect2, varscan2
